Gene-level copy-number profile of tumor specimen HCM-STAN-0840-C49-06A from HCMI case HCM-STAN-0840-C49, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Giant cell sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 67.4 years (24,606 days).
Specimen HCM-STAN-0840-C49-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 801ea4a3-ecb2-4462-926d-ec694e146b86.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-STAN-0840-C49-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/fe979dc9-2f6a-4ec7-8b81-1cd71db2b8df

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 262; copy number 1: 210; copy number 2: 43,920; copy number 3: 5,565; copy number 4: 6,107; copy number 5: 1,581; copy number 6: 119; copy number 7: 609; copy number 8: 2; copy number 9: 7; copy number 10: 7; copy number 19: 2.

Homozygous deletions (total copy number 0; autosomes only): 262 genes in 58 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–133,723, 11 genes (within-gene range 0–2): DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5, AL627309.1, AL627309.3.
- chr2:7,725,801–7,737,095, 3 genes: LINC01871, AC092580.3, AC092580.1.
- chr2:19,348,429–19,520,095, 4 genes: MIR4757, OSR1, AC010096.1, LINC01808.
- chr2:173,811,076–174,043,880, 7 genes: AC106900.1, RPL5P7, SP3, AC016737.1, AC016737.2, LINC01960, RPSAP24.
- chr2:181,422,154–181,538,940, 2 genes (within-gene range 0–4): AC020595.1, ITGA4.
- chr2:183,904,529–184,382,869, 3 genes: AC093639.1, AC020584.1, MIR548AE1.
- chr2:185,652,374–187,556,288, 22 genes (within-gene range 0–4): FSIP2-AS1, U8, FSIP2-AS2, FSIP2, RPL21P32, LINC01473, AC104058.1, RPL23AP35, AC017071.1, MED28P3, ZC3H15, DPRXP1, ITGAV, AC017101.1, FAM171B, ZSWIM2, IMPDH1P7, AC007319.1, RN7SKP42, RNU6-989P, CALCRL, GAPDHP59.
- chr2:196,260,024–196,289,707, 2 genes (within-gene range 0–5): HECW2-AS1, RN7SL820P.
- chr2:199,191,059–199,471,266, 3 genes (within-gene range 0–4): RNU7-147P, SATB2, AC016746.1.
- chr2:199,608,068–199,750,341, 2 genes: LINC01877, SEPHS1P6.
- chr2:206,640,073–206,721,570, 5 genes: AC010731.2, FAM237A, DYTN, VPS26CP1, Y_RNA.
- chr2:206,798,325–206,926,876, 2 genes: AC008269.1, AC008269.2.
- chr2:208,236,229–208,358,746, 4 genes: IDH1, IDH1-AS1, PIKFYVE, MYL6BP1.
- chr2:212,581,357–213,021,545, 7 genes (within-gene range 0–5): AC093865.1, LINC01878, PCED1CP, AC108066.1, MIR4776-1, MIR4776-2, AC108066.2.
- chr2:215,178,791–215,310,947, 2 genes: AC092844.1, LINC02862.
- chr2:216,995,906–217,251,875, 2 genes: AC007749.1, RN7SKP43.
- chr2:224,464,682–224,585,397, 3 genes: AC073052.1, CUL3, ANKRD49P1.
- chr2:225,399,710–225,762,112, 4 genes (within-gene range 0–4): NYAP2, AC016717.1, AC016717.2, AC016717.3.
- chr2:226,835,581–227,314,792, 4 genes (within-gene range 0–3): RHBDD1, AC073149.1, COL4A4, COL4A3.
- chr2:227,610,090–227,718,028, 5 genes: C2orf83, SCYGR3, AC064853.1, SCYGR4, SLC19A3.
- chr2:227,979,955–228,181,687, 2 genes: SPHKAP, RNU6-624P.
- chr2:230,034,982–230,580,006, 13 genes: SLC16A14, RNY4P19, AC009950.1, AC009950.2, SP110, SP140, SP140L, AC009949.1, SP100, RN7SL834P, HMGB1P3, AC010149.1, TPM3P8.
- chr2:230,836,909–231,025,055, 9 genes: AC012507.2, ITM2C, GCSIR, GPR55, AC012507.1, AC012507.3, COX20P2, SPATA3-AS1, SPATA3.
- chr2:231,198,546–231,376,848, 3 genes: ARMC9, RPS28P4, MIR4777.
- chr2:234,682,668–234,745,606, 2 genes: LINC01173, AC104394.1.
- chr2:236,153,071–236,168,386, 2 genes (within-gene range 0–2): Y_RNA, GBX2.
- chr2:237,858,893–237,912,106, 2 genes: RAMP1, SNORD39.
- chr2:238,320,441–238,457,520, 5 genes: TRAF3IP1, RNU6-234P, ASB1, AC016999.1, AC016999.2.
- chr2:241,356,285–241,582,726, 8 genes: FARP2, AC005104.2, MIR3133, KCTD5P1, STK25, BOK-AS1, BOK, AC133528.1.
- chr4:4,126,659–4,150,421, 2 genes: OR7E103P, UNC93B4.
- chr5:892,884–919,357, 2 genes: TRIP13, AC122719.3.
- chr6:32,549,940–32,589,848, 3 genes: RNU1-61P, HLA-DRB6, HLA-DRB1.
- chr9:21,802,636–23,898,054, 27 genes: MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2, ELAVL2, AL365204.1, AL365204.2.
- chr9:60,914,407–61,627,683, 14 genes: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D.
- chr14:106,257,762–106,324,760, 14 genes (within-gene range 0–3): IGHV3-22, IGHVII-22-1, IGHVIII-22-2, IGHV3-23, IGHV1-24, HOMER2P2, LINC00226, IGHV3-25, IGHVIII-25-1, IGHV2-26, IGHVIII-26-1, IGHVII-26-2, IGHV7-27, IGHV4-28.
- chr16:32,262,827–32,478,250, 10 genes: AC133485.2, AC140878.1, AC133548.2, AC133548.1, ACTR3BP3, AC138915.2, PABPC1P13, AC138915.3, AC138915.1, ABCD1P3.
- chr16:32,845,964–32,848,156, 2 genes: AC142086.2, IGHV2OR16-5.
- chr16:32,877,469–33,028,037, 12 genes: SLC6A10P, AC142086.1, IGHV3OR16-15, IGHV3OR16-6, AC142086.6, AC142086.3, AC142086.5, IGHV1OR16-2, IGHV3OR16-10, AC142086.4, IGHV1OR16-4, IGHV3OR16-8.
- chr17:18,426,861–18,551,705, 11 genes (within-gene range 0–2): KRT17P2, KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.
- chr21:13,609,858–13,654,356, 4 genes: POTED, RNU6-286P, MIR3118-1, AL050303.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,327 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,851,791–90,235,370, 36 genes, copy number 5: IGKV2D-40, IGKV1D-39, IGKV2D-38, IGKV1D-37, IGKV2D-36, IGKV1D-35, IGKV3D-34, IGKV1D-33, IGKV1D-32, IGKV3D-31, IGKV2D-30, IGKV2D-29, IGKV2D-28, IGKV1D-27, IGKV2D-26, IGKV3D-25, IGKV2D-24, IGKV2D-23, IGKV1D-22, IGKV6D-21, IGKV3D-20, IGKV2D-19, IGKV2D-18, IGKV6D-41, IGKV1D-17, IGKV1D-16, IGKV3D-15, IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42, IGKV1D-43, IGKV1D-8, IGKV3D-7.
- chr2:193,256,483–196,593,684, 27 genes, copy number 5–10 (within-gene range 0–10): SLC44A3P1, DNAJC17P1, SEC61GP1, AC068135.2, AC068135.1, GLULP6, HNRNPA1P47, LINC01821, AC106883.1, Metazoa_SRP, AC006196.1, LINC01790, AC010983.1, AC104823.1, AC064834.1, RNU6-169P, LINC01825, LINC01827, SLC39A10, AHCYP5, RNU6-915P, DNAH7, E2F3P2, AC114760.1, STK17B, AC114760.2, HECW2.
- chr2:196,639,554–197,786,762, 28 genes, copy number 5–19: CCDC150, AC068544.1, GTF3C3, C2orf66, AC012486.1, PGAP1, ANKRD44, HNRNPA3P15, RPL4P7, ANKRD44-AS1, ANKRD44-IT1, ATP5MC2P3, AC010746.2, NPM1P46, SF3B1, AC010746.1, RNU6-1029P, COQ10B, HSPD1, HSPE1, HSPE1-MOB4, MOB4, AC020550.1, RFTN2, AC020550.2, AC011997.1, MARS2, BOLL.
- chr2:200,305,881–203,315,871, 116 genes, copy number 6–10 (broad region; genes not listed).
- chr2:203,634,577–203,873,965, 7 genes, copy number 6: AC125238.2, AC125238.1, CD28, KRT18P39, NPM1P33, RNU6-474P, CTLA4.
- chr2:212,999,691–213,152,427, 1 gene, copy number 5 (within-gene range 0–5): IKZF2.
- chr2:219,903,900–220,049,272, 4 genes, copy number 7: LINC01803, AC008281.1, MIR4268, AC009310.1.
- chr2:220,127,546–220,212,491, 1 gene, copy number 7 (within-gene range 3–7): AC093083.1.
- chr2:233,775,679–233,854,566, 2 genes, copy number 8: MROH2A, HJURP.
- chr3:195,650,146–195,657,927, 2 genes, copy number 5: AC233280.2, AC233280.1.
- chr7:37,032–35,800,676, 604 genes, copy number 7 (broad region; genes not listed).
- chr7:62,275,361–63,248,321, 12 genes, copy number 5: AC128676.1, RNU6-417P, AC069285.2, AC069285.3, ZNF90P3, SAPCD2P4, SEPTIN14P1, AC069285.1, AC092001.1, PHKG1P1, AC006455.8, SEPTIN7P4.
- chr7:69,186,821–69,430,923, 1 gene, copy number 5 (within-gene range 4–5): AC092100.1.
- chr7:69,330,698–69,597,493, 5 genes, copy number 5: MTCO2P25, MTCO1P25, RNU6-229P, Y_RNA, CT66.
- chr7:75,493,625–77,640,069, 64 genes, copy number 5 (broad region; genes not listed).
- chr7:79,452,877–153,413,985, 1,398 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:159,231,435–159,233,377, 1 gene, copy number 5: PIP5K1P2.
- chr15:34,489,002–34,521,791, 3 genes, copy number 5: HNRNPLP2, FSCN1P1, DNM1P5.
- chr19:18,340,598–18,569,387, 15 genes, copy number 5 (within-gene range 4–5): PGPEP1, GDF15, MIR3189, LRRC25, SSBP4, ISYNA1, AC010335.1, ELL, AC010335.2, AC010335.3, AC005387.1, FKBP8, AC005387.2, KXD1, AC005253.1.

Autosomal genes at a single copy (total copy number 1): 210. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
